Somatic mutation profile of tumor specimen TCGA-IA-A83W-01A (aliquot TCGA-IA-A83W-01A-11D-A34Z-10) from TCGA case TCGA-IA-A83W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 70.3 years (25,678 days).
Specimen TCGA-IA-A83W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53de1db0-e4ac-47fe-8ab5-d908f2cd766d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IA-A83W-11A (Solid Tissue Normal), aliquot TCGA-IA-A83W-11A-11D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99dcb1e6-5904-43b4-b1d1-74d07de2b785

The open-access MAF lists 75 somatic variants for this specimen: 60 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 49, Silent 15, Frame Shift Del 5, Nonsense Mutation 3, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3749T>C p.M1250T | Missense Mutation (SNP) | VAF 32/79 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913245, CM992181, COSV59255872; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSF2 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.582); catalogued as COSV51973756; called by muse, mutect2, varscan2
- ADARB1 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100653618; called by muse, mutect2
- ALPK2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100864139; called by muse, mutect2, varscan2
- ANKRD35 | c.1855G>T p.V619L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100841637; called by muse, mutect2, varscan2
- APCDD1L | c.1401G>T p.Q467H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100953930; called by muse, mutect2, varscan2
- BHLHE40 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99847947; called by muse, mutect2, varscan2
- BIRC6 | c.12028T>C p.S4010P | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs748637705, COSV101134328; called by muse, mutect2, varscan2
- BRD4 | c.3952C>T p.Q1318* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV99649975; called by muse, varscan2
- CACNB4 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV99137795; called by muse, varscan2
- CCND3 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100882184, COSV65913478; called by muse, mutect2, varscan2
- CCZ1B | c.250T>A p.L84I | Missense Mutation (SNP) | VAF 131/474 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV100367736; called by muse, mutect2, varscan2
- CHD8 | c.6727del p.R2243Afs*19 (on ENST00000646647 / NM_001170629.2; = p.R1964Afs*19 on NM_020920.4) | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | catalogued as COSV63036650; called by mutect2, pindel, varscan2
- CNTNAP4 | c.3422T>C p.L1141P | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100269487; called by muse, mutect2, varscan2
- CRISPLD1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100081613; called by muse, mutect2, varscan2
- DNAH9 | c.8166A>T p.E2722D | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99304287; called by muse, mutect2, varscan2
- EFTUD2 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV101274516; called by muse, mutect2, varscan2
- FAM153B | c.670A>T p.I224F (on ENST00000253490; = p.I147F on NM_001265615.1) | Missense Mutation (SNP) | VAF 123/596 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.125); catalogued as COSV99498774, COSV99499061; called by muse, mutect2, varscan2
- FBXL20 | c.745T>A p.L249I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV99233760; called by muse, mutect2, varscan2
- FMO1 | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as COSV100707696; called by muse, mutect2, varscan2
- GABPB2 | c.778T>C p.S260P | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV100927188; called by muse, mutect2, varscan2
- GCM1 | c.1009T>C p.F337L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99452136; called by muse, mutect2, varscan2
- GJC3 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV57210977; called by muse, mutect2, varscan2
- GJD3 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100492180; called by muse, mutect2, varscan2
- GNL2 | c.2143A>C p.N715H | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.188); catalogued as COSV99953487; called by muse, mutect2, varscan2
- GUCY1A2 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV99972938; called by muse, mutect2, varscan2
- H3C8 | c.266C>A p.A89E | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100010011; called by muse, mutect2
- HYPK | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99979633; called by muse, mutect2, varscan2
- IGFBP2 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922678795, COSV52081460; called by muse, mutect2, varscan2
- IL32 | c.388G>A p.G130S (on ENST00000396890 / NM_001308078.4; = p.G84S on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.048); catalogued as rs779453646, COSV50403710; called by muse, mutect2, varscan2
- IPO9 | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100843342; called by muse, mutect2, varscan2
- MAPKBP1 | c.2176T>C p.C726R (on ENST00000456763 / NM_001128608.2; = p.C720R on NM_014994.3) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528965; called by muse, mutect2, varscan2
- MEAK7 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1567502243, COSV100640364; called by muse, mutect2
- MSL2 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV99386481; called by muse, mutect2, varscan2
- MYH10 | c.3647A>C p.K1216T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99344177; called by muse, mutect2, varscan2
- N6AMT1 | c.97T>A p.L33M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.285); catalogued as COSV100374869; called by muse, mutect2, varscan2
- NAGLU | c.1950del p.P651Qfs*156 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as CM137951; called by mutect2, pindel, varscan2
- NECAP1 | c.582A>T p.K194N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV100331529; called by muse, mutect2, varscan2
- OPA1 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100655165; called by muse, mutect2, varscan2
- ORC2 | c.284A>T p.Y95F | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV99309398; called by muse, mutect2, varscan2
- PBRM1 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs747444363, COSV99967466; called by muse, mutect2, varscan2
- POU5F2 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1245301914, COSV67937955; called by muse, mutect2, varscan2
- PRDM14 | c.1551C>A p.F517L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99399894; called by muse, mutect2, varscan2
- SLC25A3 | c.545C>T p.P182L (on ENST00000228318 / NM_005888.3; = p.P181L on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99498986; called by muse, mutect2, varscan2
- SLC4A7 | c.2326A>C p.N776H | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99839236; called by muse, mutect2, varscan2
- STK11IP | c.2491G>A p.V831M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV99822265; called by muse, mutect2, varscan2
- TCF20 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs886376549, COSV100166292; called by muse, mutect2, varscan2
- TESK1 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99427289; called by muse, mutect2, varscan2
- TUT7 | c.2767C>A p.L923I | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV99462461; called by muse, varscan2
- VPS13D | c.12911A>G p.Y4304C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99165523; called by muse, mutect2, varscan2
- WDFY3 | c.3719C>T p.P1240L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99882158; called by muse, mutect2, varscan2
- ARL3 | c.148-1_176del p.X50_splice | Splice Site (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel
- FBXO31 | c.1338del p.F446Lfs*7 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- IFT80 | c.1213del p.S405Hfs*8 | Frame Shift Del (DEL) | VAF 146/345 reads (42%) | called by mutect2, pindel, varscan2
- MIB1 | c.2813del p.K938Rfs*30 | Frame Shift Del (DEL) | VAF 73/243 reads (30%) | called by mutect2, pindel, varscan2
- MTX1 | c.361_369del p.I121_G123del | In Frame Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel
- PCGF2 | c.770A>G p.E257G | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- RPL18A | c.518dup p.N173Kfs*? | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- S1PR5 | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2
- TM2D1 | c.228_230del p.Y76_T77delins* | Nonsense Mutation (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel*, varscan2*
- ACTN4 | c.1641C>T p.A547= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99399804; called by muse, mutect2, varscan2
- ANKRD36B | c.1050C>A p.G350= | Silent (SNP) | VAF 101/535 reads (19%) | catalogued as rs772956561, COSV99307947; called by muse, mutect2, varscan2
- ATP6V1A | c.705T>C p.D235= | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as COSV99849877; called by muse, mutect2, varscan2
- DOHH | c.510G>T p.R170= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99170980; called by muse, mutect2, varscan2
- FAM53B | c.93G>A p.K31= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV55103109, COSV99784822; called by muse, mutect2, varscan2
- GOLGA4 | c.1980A>G p.K660= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV100728666; called by muse, mutect2, varscan2
- JARID2 | c.3396G>A p.L1132= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100521351; called by muse, mutect2, varscan2
- KANK1 | c.3993T>G p.S1331= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV101206834; called by muse, mutect2, varscan2
- KLHL31 | c.1578C>T p.R526= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100911733; called by muse, mutect2, varscan2
- MACF1 | c.6096C>A p.I2032= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as COSV99241452; called by muse, mutect2, varscan2
- MEX3B | c.105G>A p.Q35= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100313863; called by muse, mutect2, varscan2
- MUC16 | c.41733C>T p.S13911= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV101109625, COSV101110102; called by muse, mutect2, varscan2
- OSBPL5 | c.2025G>A p.E675= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs1422272010, COSV99720044; called by muse, mutect2, varscan2
- PPP2R2A | c.771G>A p.R257= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100276985; called by muse, mutect2, varscan2
- TRPM4 | c.2889G>A p.L963= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1221675016, COSV99419072; called by muse, mutect2, varscan2
